Surgical pathology report (de-identified scan), TCGA case TCGA-09-1667, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1667-01C (Primary Tumor).

[page 1 of 6]
FINAL PATHOLOGIC DIAGNOSIS

A. Left ovary and fallopian tube, resection:

Papillary serous carcinoma, present as 1.5 cm mass involving left ovary and 1.2 cm

mass involving fallopian tube; tumor present on ovarian cortical surface and tubal

serosal surface; see comment.

B. Right ovary, fallopian tube, and vermiform appendix, resection:

1. Papillary serous carcinoma present as 2.1 cm mass involving right ovary and

multiple small nodules (largest 0.4 cm) involving right fallopian tube; tumor

present on ovarian cortical surface and tubal serosal surface; see comment.

2. Vermiform appendix with serosal adhesions binding it to ovary and fallopian

tube; no direct extension of tumor into appendix identified.

C. Uterus, hysterectomy:

1. Cervix with no significant pathologic abnormalities.

2. Benign atrophic endometrium.

3. Myometrium with no significant pathologic abnormalities.

4. Uterine serosa with focal fibrous adhesions.

5. No carcinoma identified.

D. "Right para-rectal tumor", biopsy:

Papillary serous carcinoma, infiltrating fibroadipose tissue.

E. "Left para-rectal tumor", biopsy:

Papillary serous carcinoma, infiltrating fibroadipose tissue.

Page 1 of 5

F. Left pelvic lymph nodes, excision:

Fourteen lymph nodes with no tumor identified (0/14).

G. Left common iliac lymph nodes, excision:

Five lymph nodes with no tumor identified (0/5).

H. Left peri-aortic lymph nodes, excision:

Three lymph nodes with no tumor identified (0/3).

I. Right pelvic lymph nodes, excision:

Eleven lymph nodes with no tumor identified (0/11).

J. Right common iliac lymph nodes, excision:

Five lymph nodes with no tumor identified (0/5).

K. Right peri-aortic lymph nodes, excision:

One lymph node with no tumor identified (0/1).

L. "Ileum nodules", excision:

Tissue consistent with serosal adhesions; no lymph nodes or tumor

[page 2 of 6]
identified.

M. "Omentum", biopsy:

Vascular adipose tissue consistent with omentum; no tumor identified.

N. "Omentum #2", biopsy:

Vascular adipose tissue consistent with omentum; no tumor identified.

O. "Omentum #3", biopsy:

Vascular adipose tissue

consistent with omentum; no tumor identified.

COMMENT:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary serous carcinoma.
2. Grade of tumor: 2/3 (moderately differentiated).
3. Location of tumor: Bilateral.
4. Diameter of tumor: 1.2 cm (left), 2.1 cm (right).
5. Appearance of surface of ovary: Tumor on surface.
6. Condition of capsule: Intact.
7. Appearance of cut surface: Solid and cystic, mainly solid.
8. Color of solid areas: White.
9. Necrosis: Not identified.
10. Lymphatic/vascular invasion: Not identified.
11. Sites of metastases in pelvis: Fallopian tube, right and left para-rectal regions.
12. Pelvic lymph nodes: 0/35 contain metastatic tumor.
13. Sites of metastases in abdomen: None.
14. Para-aortic lymph nodes: 0/4 contain metastatic tumor.
15. Peritoneal cytology: Positive (Cytology accession number: [REDACTED])
16. Other significant findings: Adhesion of vermiform appendix to right adnexa.
17. FIGO stage: IIC (if no distant metastases present).
18. TNM stage: pT2cN0MX (IIC if no distant metastases present).

Page 2 of 5

Specimen(s) Received

A:Left adnexa (FS)

B:Right ovary and tube with appendix (FS)

C:Uterus and cervix

D:Right pararectal tumor

E:Left pararectal tumor

F:Left pelvic lymph nodes

G:Left common iliac lymph nodes

H:Left periaortic lymph nodes

I:Right pelvic lymph nodes

J:Right common iliac lymph nodes

K:Right periaortic lymph nodes

L:Ileum nodules

M:Omentum 1

N:Omentum 2

O:Omentum 3

Intraoperative Diagnosis

FS1(A). Left adnexa: High grade carcinoma, favor serous, present on both fallopian tube and ovarian

[page 3 of 6]
[REDACTED]
FS2(B). Right adnexa, biopsy: High grade carcinoma, favor serous, present on ovarian surface. ([REDACTED])
[REDACTED]

Clinical History

The patient is a [REDACTED] with bilateral pelvic masses, increase in CA-125 to 930, and abnormal bleeding. She undergoes hysterectomy and bilateral salpingo-oophorectomy and numerous abdominal/pelvic biopsies.

Gross Description

The specimen is received in fifteen parts, each labeled with the patient's name and medical record number.

Parts A and B are received fresh from the Operating Room. Parts C through O are received in formalin.

Part A is received fresh and is additionally labeled "Left adnexa." It consists of an ovary and attached fallopian tube, weighing 105 gm and measuring 9.1 x 4.5 x 3.8 cm in aggregate. The ovary measures 3.5 x 3.0 x 1.8 cm. The fallopian tube measures 7.0 cm in length and 1.0 cm in average diameter. The end of the fallopian tube has a papillary, white-brown mass protruding from it. The ovary has a papillary mass, measuring 3.0 x 2.0 x 1.0 cm, attached to the external surface and growing toward the fallopian tube. The external surface is otherwise unremarkable. The ovary and fallopian tube are bisected, demonstrating a firm nodule, measuring 1.5 cm, within the central aspect of the ovary. Additionally, there is a papillary, white-tan nodule, measuring 1.2 cm, within the tubal fimbria. No other lesions are noted. A portion of the papillary mass on the fimbria as well as from the surface of the ovary is submitted for frozen section

diagnosis as FS1, with the frozen section remnant submitted in cassette A1.

Representative sections of the remainder of the tissue is submitted as follows:

Cassette A2: Section of fallopian tube fimbria with tumor on exterior.

Cassette A3: Cross section of ovary with nodule.

Cassette A4: Representative section of ovary with tumor in relationship to capsule.

Cassette A5: Relationship of ovary with papillary tumor on exterior of ovary.

Cassette A6: Cross section of fallopian tube with intraluminal tumor.

Part B is received fresh and is additionally labeled "Right ovary and tube with appendix." It consists of an irregular fragment of tissue, consisting of ovary (measuring 3.5 x 2.8 x 2.1 cm), fallopian tube (measuring

Page 3 of 5

5.0 cm in length and 1.0 cm in diameter), and appendix (measuring 4.1 cm in length and 0.8 cm in diameter). The specimen weighs 33 gm in aggregate. The ovary is generally white-tan, smooth, and

[page 4 of 6]
[REDACTED]

glistening; however, there is a firm, nodular area, measuring 0.4 cm in diameter, on the exterior surface of the ovary, surrounded by fine, white-tan, papillary structures. The fallopian tube also has numerous small, papillary nodules, ranging in size from 0.1 to 0.4 cm in diameter, scattered over the exterior surface of the fallopian tube. The external appearance of the appendix is unremarkable. The appendix appears to be adherent to the fallopian tube and ovary. The ovary is bisected to reveal a firm, white-tan, nodular mass, measuring 2.1 cm in greatest dimension, which extends to the surface to create a portion of the nodule, already described, on the exterior surface of the ovary. Tissue from this region is submitted for frozen section diagnosis as FS2, with the frozen section remnant submitted in cassette B1. The distal one third of the appendix is longitudinally sectioned and submitted in cassette B2. The remainder of the appendix is cross sectioned and submitted in cassette B3. The remainder of the tissue is submitted as follows:

Cassettes B4-B5: Sections of ovary showing relationship of tumor nodule to ovary.
Cassette B6: Representative sections of fallopian tube with papillary nodules on surface.

Part C is additionally labeled "Uterus and cervix." It consists of a total hysterectomy specimen (without attached adnexa), weighing 43 gm and measuring 6.5 cm from superior to inferior, 3.5 cm from cornu to cornu, and 3.5 cm from anterior to posterior. The cervix measures 3.0 x 2.0 cm of the face of the exocervix, with a slit-like os, measuring 0.4 cm in length. The external surface of the uterus is grossly unremarkable, with no nodules or papillary structures noted. The specimen is inked so that the posterior surface is black and the anterior surface is blue. The specimen is then bivalved to reveal a cervical canal that measures 2.5 cm in length. There are no obvious lesions identified within the uterine cavity. The myometrium measures 1.1 cm in thickness. Tissue is submitted as follows:

Cassette C1: Anterior cervix.

Cassette C2: Posterior cervix.

Cassettes C3-C4: Myometrium with overlying endometrium.

Part D is additionally labeled "Right pararectal tumor." It consists of two unoriented, irregular fragments of red-brown soft tissue, measuring 3.2 x 3.1 x 1.8 cm in aggregate. The specimen is serially sectioned to

reveal a firm, white, encapsulated nodule, measuring 1.0 cm in diameter. The specimen is entirely submitted in cassettes D1 through D3.

Part E is additionally labeled "Left pararectal tumor." It consists of a single unoriented, irregular fragment of firm tissue, measuring 3.0 x 0.8 x 0.9 cm. The specimen is serially sectioned and entirely submitted in

[page 5 of 6]
[REDACTED]
cassettes E1 through E3.

Part F is additionally labeled "Left pelvic lymph nodes." It consists of numerous unoriented, irregular fragments of yellow-brown fibrofatty tissue, measuring 3.5 x 2.8 x 0.8 cm in aggregate. The specimen is entirely submitted in cassettes F1 through F4.

Part G is additionally labeled "Left common iliac lymph nodes." It consists of numerous unoriented, irregular fragments of yellow-brown fibrofatty tissue, measuring 1.0 x 0.8 x 0.6 cm in aggregate. The specimen is entirely submitted in cassette G1.

Part H is additionally labeled "Left periaortic lymph nodes." It consists of numerous unoriented, irregular fragments of fibrofatty tissue, measuring 1.8 x 1.1 x 0.7 cm in aggregate. The largest lymph node measures 1.3 cm in greatest dimension; this lymph node is bisected and submitted in cassette H1. The remainder of the lymph node candidates and all remaining soft tissue are entirely submitted in cassette H2.

Part I is additionally labeled "Right pelvic lymph nodes." It consists of numerous unoriented, irregular fragments of fibrofatty tissue, measuring 3.5 x 2.3 x 1.7 cm in aggregate. The specimen is entirely submitted in cassettes I1 through I3.

Part J, additionally labeled "Right common iliac lymph node," consists of a single irregular, unoriented fragment of yellow-brown, fibrofatty tissue, measuring 1.8 x 1.0 x 0.6 cm. The specimen is entirely submitted in cassettes J1 and J2.

Part K, additionally labeled "Right periaortic lymph node," consists of a single irregular, unoriented fragment of fibrofatty tissue, measuring 0.8 x 0.7 x 0.6 cm. The specimen is bisected and submitted entirely in cassette K1.

Part L, additionally labeled "Ileum nodes," consists of numerous irregular, unoriented fragments of red-brown, firm tissue, measuring 0.4 x 0.3 x 0.1 cm. The specimen is entirely submitted in cassette L1.

Part M, additionally labeled "Omentum," consists of a single irregular, unoriented fragment of yellow-brown, fibrofatty tissue, measuring 8.5 x 9.5 x 0.9 cm. No nodules or other abnormalities are identified. The specimen is serially sectioned to reveal no masses, nodules, or other lesions. A representative section is submitted in cassettes M1-M2.

Part N, additionally labeled "Omentum 2," consists of a single irregular, unoriented fragment of yellow-brown, fibrofatty tissue, measuring 16.1 x 9.3 x 0.9 cm. No nodules, masses, or other lesions are identified in the specimen. It is serially sectioned to reveal no abnormalities. A representative section is

[page 6 of 6]
[REDACTED]

submitted in cassettes N1-N2.

Part O, additionally labeled "Omentum 3," consists of a single irregular, unoriented fragment of yellow, fibrofatty tissue, measuring 20.1 x 5.2 x 0.9 cm. The specimen does not contain any nodules, masses, or other lesions. It is serially sectioned to reveal no abnormalities. A representative section is submitted in cassettes O1-O2.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file c4e4325b-f8b2-4c45-9a3a-e670dc6f5eb4 (TCGA-09-1667.0F3FBC34-6DCE-467F-A837-442815EBC159.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).